Somatic mutation profile of tumor specimen TCGA-OR-A5LO-01A (aliquot TCGA-OR-A5LO-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LO, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 61.2 years (22,370 days).
Specimen TCGA-OR-A5LO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35910788-33c4-4fe0-b1cb-1b43a0735184.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LO-10A (Blood Derived Normal), aliquot TCGA-OR-A5LO-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c825a34-69aa-41ad-b5d8-65958da795bb

The open-access MAF lists 71 somatic variants for this specimen: 51 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Nonsense Mutation 3, In Frame Del 2, Intron 1, RNA 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs1477975265; called by muse, mutect2, varscan2
- CD163L1 | c.2163G>T p.M721I | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs746808608, COSV58023836; called by muse, mutect2, varscan2
- CSN1S1 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1162779549, COSV55892664; called by muse, mutect2, varscan2
- CXorf21 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV66762713; called by muse, mutect2
- DIO3 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV63772996; called by muse, mutect2, varscan2
- EPS8 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV99842731; called by muse, mutect2, varscan2
- GFAP | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 65/80 reads (81%) | catalogued as COSV53650853; called by muse, mutect2, varscan2
- KRT72 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs766532753, COSV53373404; called by muse, mutect2, varscan2
- LRRC4C | c.1633G>C p.V545L | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV99539330; called by muse, mutect2
- NIPAL4 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs750433431; called by muse, mutect2, varscan2
- NOS3 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769779233; called by muse, mutect2, varscan2
- OR11H1 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 130/431 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV53271630, COSV53271829; called by muse, mutect2, varscan2
- PAPPA2 | c.3568C>G p.Q1190E | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62811153; called by muse, mutect2, varscan2
- PNLIP | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1438228056; called by muse, mutect2, varscan2
- PTPN9 | c.994C>G p.R332G | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60723100; called by muse, mutect2, varscan2
- RNASEH2A | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 120/270 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV55551149; called by muse, mutect2, varscan2
- TRIM60 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371675727, COSV61970186; called by muse, mutect2, varscan2
- TXNIP | c.1164_1166del p.N389del | In Frame Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs1553765789; called by pindel, varscan2
- VCAN | c.5169G>T p.K1723N | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV54110798, COSV54113488, COSV54117868; called by muse, mutect2
- ZMIZ2 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 39/277 reads (14%) | catalogued as rs766666916; called by muse, mutect2, varscan2
- ZNF112 | c.1705C>G p.Q569E (on ENST00000337401 / NM_001083335.2; = p.Q563E on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV61619475; called by mutect2, varscan2
- ARHGAP21 | c.865A>G p.N289D | Missense Mutation (SNP) | VAF 87/405 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- BFAR | c.1213C>A p.L405I | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CD83 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CSN1S1 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- CTRL | c.794G>C p.*265Sext*35 | Nonstop Mutation (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2
- ELK4 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GIPR | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- GNE | c.2170G>C p.D724H (on ENST00000396594 / NM_001128227.3; = p.D693H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- H1-4 | c.304T>A p.S102T | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HS6ST2 | c.804C>A p.H268Q | Missense Mutation (SNP) | VAF 104/485 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ILKAP | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- KLHL15 | c.1090_1092del p.D364del | In Frame Del (DEL) | VAF 98/216 reads (45%) | called by mutect2, varscan2
- L1CAM | c.1912G>T p.A638S | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- LVRN | c.1799A>G p.N600S | Missense Mutation (SNP) | VAF 91/352 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MAST4 | c.7096G>A p.D2366N (on ENST00000403625 / NM_001164664.2; = p.D2177N on NM_015183.3) | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- METTL14 | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- MUC16 | c.21436G>C p.E7146Q | Missense Mutation (SNP) | VAF 200/452 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.629); called by muse, varscan2
- NLRP12 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- PAK5 | c.1652C>A p.S551* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- PDE9A | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PRKAR1A | c.503-1G>A p.X168_splice | Splice Site (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- PTPN4 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAPH1 | c.2623C>G p.P875A | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SLC1A5 | c.1537C>G p.P513A | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R5 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TOX3 | c.1498C>G p.Q500E | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, mutect2
- TTF2 | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TTN | c.24590C>T p.T8197I (on ENST00000591111; = p.T7270I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/66 reads (48%) | PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ZEB1 | c.1975A>C p.N659H | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ZNF135 | c.1447C>A p.Q483K (on ENST00000313434 / NM_001289401.2; = p.Q495K on NM_003436.4) | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- CAMK4 | c.1239C>A p.A413= | Silent (SNP) | VAF 36/118 reads (31%) | called by muse, mutect2, varscan2
- CENPH | c.15C>G p.P5= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- CEP128 | c.2748C>G p.L916= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs201355718; called by muse, mutect2, varscan2
- CXorf21 | c.585G>A p.E195= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as COSV100973244; called by muse, mutect2
- EBF3 | c.1542C>T p.S514= (on ENST00000355311 / NM_001375392.1; = p.S505= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs369433267, COSV62482933; called by muse, mutect2, varscan2
- LDLR | c.2295G>C p.V765= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as CD162622; called by muse, mutect2, varscan2
- MCM7 | c.198T>A p.I66= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- NEFL | c.1215G>A p.V405= | Silent (SNP) | VAF 50/61 reads (82%) | called by muse, mutect2, varscan2
- NEURL1 | c.159G>T p.L53= | Silent (SNP) | VAF 51/194 reads (26%) | called by muse, mutect2, varscan2
- NLRP9 | c.2358C>G p.V786= | Silent (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- PGBD2 | c.1170G>C p.L390= | Silent (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- POFUT2 | c.25C>T p.L9= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2
- PPME1 | c.948A>G p.K316= | Silent (SNP) | VAF 60/63 reads (95%) | called by muse, mutect2, varscan2
- PREX2 | c.2931G>A p.S977= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs570753617, COSV55795646; called by muse, mutect2, varscan2
- RAD23A | c.852G>A p.L284= | Silent (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- RHBDD1 | c.72C>T p.I24= | Silent (SNP) | VAF 39/97 reads (40%) | called by muse, mutect2, varscan2
- TAF3 | c.690A>G p.P230= | Silent (SNP) | VAF 41/206 reads (20%) | catalogued as rs1434721645; called by muse, mutect2, varscan2
- USP42 | c.501C>G p.L167= | Silent (SNP) | VAF 32/172 reads (19%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-8963C>A | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, varscan2
- NBPF7 | n.1001G>C | RNA (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2, varscan2
